Somatic mutation profile of tumor specimen 0DJR1D from CCDI case PBBXKH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,027 days).
Specimen 0DJR1D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76445723-eb19-40c3-b471-a15d79de4f97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJQZJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de750a76-6050-469a-89b1-2a0eabb4a4ae

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GSC2 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV50082227; called by muse, mutect2, varscan2
- OR5M11 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs376747453; called by muse, mutect2, varscan2
- EVX2 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- GPBP1 | c.1262A>G p.Q421R | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TAF1 | c.4918C>T p.R1640* (on ENST00000373790 / NM_138923.4; = p.R1661* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 59/172 reads (34%) | called by muse, mutect2, varscan2
